Surgical pathology report (de-identified scan), TCGA case TCGA-KC-A4BN, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Cornell Medical College, specimen TCGA-KC-A4BN-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

Surgical Pathology

Department of Pathology

Surgical Pathology Laboratory

Surgical Pathology Report

[REDACTED]

CLINICAL INFORMATION:

Prostate cancer.

Specimen submitted: A. Right neurovascular margin (fs); B. Prostate gland and seminal vesicles; C. Pelvic lymph nodes

INTRAOPERATIVE DIAGNOSIS:

A. Frozen Section Diagnosis: Minute fragment of stroma. no ganglion cells identified. Reported to

GROSS DESCRIPTION:

A. Received fresh, the specimen is labeled "right neurovascular margin (fs)," and consists of a $<0.1 \times 0.1 \times 0.1$ cm portion of fatty tissue which is entirely submitted for frozen section diagnosis. Summary of sections: AFSC.

B. Received fresh, the specimen is labeled "prostate gland and seminal vesicles", and consists of a 46.5 gram radical prostatectomy specimen including a $5.0 \times 4.0 \times 3.0$ cm prostate, a $3.0 \times 2.5 \times 1.0$ cm left seminal vesicle, a $3.0 \times 0.5 \times 0.5$ cm left vas deferens, a $3.0 \times 1.5 \times 1.0$ cm right seminal vesicle and a $3.0 \times 0.5 \times 0.5$ cm right vas deferens. The right side of the specimen is inked green and the left side is inked black. The seminal vesicle base, bladder neck and apical margins are shaved and submitted. The prostate is serially sectioned from the apex to base with sections designated from A to E respectively. On sectioning, multiple nodular and cystic areas are seen. The prostate is submitted in alternating sections. Summary of sections: B1-right seminal vesicle and vas deferens; B2-left seminal vesicle and vas deferens; B3-right base anterior; B4-right base posterior; B5-left base anterior; B5-left base posterior; B7-right apex anterior; B8-right apex posterior; B9-left apex anterior; B10-left apex posterior; B11- : B12- : B13- : B14- : B15- : B16- : B17- : B18- : B19- mid; B20- : B21- : B22- : B23- : B24- : Note: (R=Right; L=Left; A=Anterior; P=posterior).

CCT: Adenocarcinoma, acinar 8550/3
Path: Adenocarcinoma, NIS 8140/3
Site: Prostate, NOS Cdx.9
JW 9/26/12

ICD-0-3

[page 2 of 3]
C. Received fresh, the specimen is labeled "pelvic lymph nodes," and consists of an aggregate of fatty tissue which measures 5.0 x 4.0 x 1.0 cm. Multiple lymph nodes are identified within the specimen is entirely submitted. Summary of sections: C1-one lymph node bisected; C2-C8-remaining lymph nodes.

DIAGNOSIS:

- A. Prostate gland, right neurovascular margin (biopsy):
Benign prostatic tissue, (benign glands are seen only on the frozen section control slide).
- B. Prostate gland and seminal vesicles (radical prostatectomy):
Adenocarcinoma, Gleason score 7 (3 + 4).
The tumor is present in the right lobe only and is organ-confined.
The surgical resection margins and seminal vesicles are free of tumor.
Please see attached staging summary.
- C. Lymph nodes, pelvis (excision):
Six lymph nodes, negative for metastatic carcinoma (0/6).

SYNOPTIC DIAGNOSIS:

Histologic Type:	Adenocarcinoma
(conventional, not otherwise specified)	
Tumor Quantitation:	Primary Pattern: Grade 3
prostatic tissue involved by tumor: 5%	Secondary Pattern: Grade 4
Pathologic Staging (pTNM):	Total Gleason Score: 7
involving one-half of 1 side (lobe) or less	Proportion (percent) of
node metastasis	pT2a: Unilateral,
nodes examined: 6	pN0: No regional lymph
nodes involved: 0	Number of regional lymph
cannot be assessed	Number of regional lymph
Margins:	pMX: Distant metastasis
invasive carcinoma	Margins uninvolved by
Extraprostatic Extension:	Absent
Seminal Vesicle Invasion:	Absent
Perineural Invasion:	Present
Additional Pathologic Findings:	High-grade prostatic
intraepithelial neoplasia (PIN)	Other: Organized,
thrombosed periprostatic veins	

** Electronically Signed Out **

Attending Pathologist

The attending pathologist whose signature appears on this report has reviewed the diagnostic slides, and has edited the gross and microscopic portions of the report in rendering the final diagnosis.

ICD9 Codes: . . .

SNOMED:

[page 3 of 3]
Slides: A-2, B-30, C-8
Resulting Agency

IIPA Discrepancy		

8/24/12

Source: NCI Genomic Data Commons file 20673659-758f-49dc-9b9f-14d836505bdb (TCGA-KC-A4BN.A929648E-54E0-4215-9148-4E1498961697.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).